Somatic mutation profile of tumor specimen MP2PRT-PASJSX-TMP1-A (aliquot MP2PRT-PASJSX-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASJSX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,155 days).
Specimen MP2PRT-PASJSX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c806f15e-bb4b-442e-b8b1-6c9efec7183f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASJSX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASJSX-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da8e1352-7262-4bb6-8525-b968816d9d49

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, 5'Flank 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM32 | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1564482697; called by muse, varscan2
- CROCC2 | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 104/330 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as rs537774664, COSV104435368; called by muse, mutect2, varscan2
- DSCAML1 | c.385G>A p.D129N (on ENST00000321322; = p.D69N on NM_020693.4) | Missense Mutation (SNP) | VAF 33/508 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs529321691; called by muse, mutect2
- EXOC6B | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 80/346 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as rs761382111; called by muse, varscan2
- FTMT | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 36/590 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV58419694; called by muse, mutect2
- LRRTM4 | c.1048G>T p.V350F | Missense Mutation (SNP) | VAF 77/390 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV69139301; called by muse, mutect2, varscan2
- LYPD4 | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV58027712; called by muse, mutect2
- MUC17 | c.10799C>T p.S3600F | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60291820; called by muse, mutect2
- NRAS | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as rs866005906; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2
- SFXN3 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 85/407 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs754285325; called by muse, mutect2, varscan2
- TUBB4B | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 100/494 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61117678; called by muse, mutect2, varscan2
- UMPS | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 63/310 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs773243224, COSV51736629; called by muse, mutect2, varscan2
- ANO5 | c.1486G>C p.E496Q | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ARHGAP39 | c.1002C>G p.F334L | Missense Mutation (SNP) | VAF 16/592 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- COL24A1 | c.4289A>G p.N1430S | Missense Mutation (SNP) | VAF 94/282 reads (33%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- DENND4C | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 51/372 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLEC1 | c.2463G>C p.L821F | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- ERAL1 | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 108/521 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAD2 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- KIAA0586 | c.2743G>C p.E915Q (on ENST00000619416 / NM_001244190.2; = p.E854Q on NM_014749.5) | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2
- PGAP6 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 110/440 reads (25%) | called by muse, varscan2
- POLN | c.1834G>T p.V612F | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- PSME4 | c.1819C>G p.Q607E | Missense Mutation (SNP) | VAF 11/303 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- TRIM55 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 69/301 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TTN | c.68929C>G p.L22977V (on ENST00000591111; = p.L15553V on NM_003319.4) | Missense Mutation (SNP) | VAF 126/466 reads (27%) | PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- VGF | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 19/630 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- BCL9 | c.1638G>A p.P546= | Silent (SNP) | VAF 16/457 reads (4%) | catalogued as rs1553204760, COSV99326107; called by muse, mutect2
- EGFLAM | c.645C>T p.A215= | Silent (SNP) | VAF 176/498 reads (35%) | catalogued as rs139882517; called by muse, mutect2, varscan2
- OR8I2 | c.720C>T p.C240= | Silent (SNP) | VAF 86/376 reads (23%) | catalogued as rs141691557, COSV100135786; called by muse, mutect2, varscan2
- PPEF1 | c.51G>C p.L17= | Silent (SNP) | VAF 69/229 reads (30%) | catalogued as COSV100583548; called by muse, mutect2, varscan2
- SSTR5 | c.1068C>T p.N356= | Silent (SNP) | VAF 76/400 reads (19%) | catalogued as rs753983181; called by muse, varscan2
- ZMYND12 | c.171G>A p.L57= | Silent (SNP) | VAF 78/409 reads (19%) | called by muse, mutect2, varscan2
- IKBIP | c.297+7885G>A | Intron (SNP) | VAF 14/428 reads (3%) | called by muse, mutect2
- TNS2 | chr12:53049224 G>C | 5'Flank (SNP) | VAF 69/320 reads (22%) | called by muse, mutect2, varscan2
